Somatic mutation profile of tumor specimen TCGA-JV-A75J-01A (aliquot TCGA-JV-A75J-01A-11D-A32I-09) from TCGA case TCGA-JV-A75J, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Uterus, NOS; Age at diagnosis: 43.8 years (16,001 days).
Specimen TCGA-JV-A75J-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c3b83292-ec28-4bb4-bfac-b8b17513b810.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-JV-A75J-10A (Blood Derived Normal), aliquot TCGA-JV-A75J-10A-01D-A32I-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5269e638-5212-4f10-b1cb-6384cb7d2552

The open-access MAF lists 25 somatic variants for this specimen: 18 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 16, Silent 7, Frame Shift Ins 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAD2 | c.1550G>A p.R517H (on ENST00000315906 / NM_001145400.2; = p.R599H on NM_139174.4) | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs374328634; called by muse, mutect2, varscan2
- ADAMTS12 | c.4065C>G p.D1355E | Missense Mutation (SNP) | VAF 35/64 reads (55%) | SIFT tolerated (0.62); PolyPhen benign (0.04); catalogued as COSV100710623; called by muse, mutect2, varscan2
- AKAP11 | c.5438C>T p.T1813M | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.05); catalogued as rs529206918; called by muse, mutect2, varscan2
- BCL2L12 | c.86T>A p.I29N | Missense Mutation (SNP) | VAF 41/99 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.555); catalogued as COSV99881008; called by muse, mutect2, varscan2
- CEP164 | c.4148G>T p.G1383V | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs913817059; called by muse, mutect2
- DNMT1 | c.519G>A p.K173= | Splice Region (SNP) | VAF 32/110 reads (29%) | catalogued as COSV100532255; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.2387A>C p.K796T | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as COSV100668540; called by muse, mutect2, varscan2
- FAT2 | c.1948T>G p.S650A | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT tolerated (0.7); PolyPhen benign (0.061); catalogued as COSV99942352; called by muse, mutect2, varscan2
- IFNLR1 | c.895A>T p.T299S | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.036); catalogued as COSV100552067; called by muse, mutect2, varscan2
- MARS2 | c.1345C>G p.L449V | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0.271); catalogued as rs1281799450, COSV99986549; called by mutect2, varscan2
- MYO9A | c.4711C>G p.L1571V | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0); catalogued as COSV100613121; called by muse, mutect2, varscan2
- NDST3 | c.1874C>T p.S625F | Missense Mutation (SNP) | VAF 38/97 reads (39%) | SIFT tolerated (0.95); PolyPhen benign (0.003); catalogued as COSV99630131; called by muse, mutect2, varscan2
- NPC1L1 | c.2986A>G p.I996V | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.5); PolyPhen benign (0.006); catalogued as COSV99204579; called by muse, mutect2, varscan2
- OR4M1 | c.748G>C p.V250L | Missense Mutation (SNP) | VAF 36/172 reads (21%) | SIFT tolerated (0.35); PolyPhen benign (0.049); catalogued as COSV100271090; called by muse, mutect2, varscan2
- OR7C1 | c.814C>G p.L272V | Missense Mutation (SNP) | VAF 6/99 reads (6%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.034); catalogued as COSV99934848, COSV99934856; called by muse, mutect2
- PLD4 | c.170C>T p.P57L | Missense Mutation (SNP) | VAF 42/100 reads (42%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as COSV66914893; called by muse, mutect2, varscan2
- RSPH4A | c.1309C>T p.P437S | Missense Mutation (SNP) | VAF 42/81 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV99994069; called by muse, mutect2, varscan2
- ELMO1 | c.2045dup p.R683Afs*3 | Frame Shift Ins (INS) | VAF 15/37 reads (41%) | called by mutect2, pindel, varscan2
- ATG2B | c.2955C>T p.G985= | Silent (SNP) | VAF 41/83 reads (49%) | catalogued as rs1314554020, COSV100737894; called by muse, mutect2, varscan2
- GABRG3 | c.1182C>T p.S394= | Silent (SNP) | VAF 65/101 reads (64%) | catalogued as rs1054566927, COSV61522536; called by muse, mutect2, varscan2
- ISM1 | c.1050C>T p.D350= | Silent (SNP) | VAF 16/33 reads (48%) | catalogued as rs572363345, COSV52603697; called by muse, mutect2, varscan2
- LENG8 | c.1545C>A p.R515= | Silent (SNP) | VAF 28/53 reads (53%) | catalogued as COSV100457323; called by muse, mutect2, varscan2
- MS4A8 | c.450A>G p.A150= | Silent (SNP) | VAF 40/66 reads (61%) | catalogued as rs1404460583, COSV100282472, COSV55753827; called by muse, mutect2, varscan2
- TRIML2 | c.1053T>A p.T351= | Silent (SNP) | VAF 16/33 reads (48%) | catalogued as COSV100455996; called by muse, mutect2, varscan2
- TSHZ1 | c.840C>T p.S280= (on ENST00000580243 / NM_001308210.2; = p.S235= on NM_005786.6) | Silent (SNP) | VAF 31/57 reads (54%) | catalogued as rs573970992, COSV100433528; called by muse, mutect2, varscan2
